CCDI case PBBISG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eb836f71-d341-4164-acf8-3c3a4360fe6d

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,781 days).

Biospecimens (2 samples)
- Sample 0D9FE3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9FE7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
